ALCHEMIST case ALCH-AF49 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/cab17b11-8acc-43da-8f18-9270437c2079

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 51.6 years (18,837 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AF49-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AF49-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AF49-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 82; Percent normal cells: 12; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
